Gene-level copy-number profile of tumor specimen TCGA-AH-6549-01A from TCGA case TCGA-AH-6549, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 66.6 years (24,337 days).
Specimen TCGA-AH-6549-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.c8cc88e1-89c7-459a-a181-0dd802a3cf55.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AH-6549-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/9645a357-35d4-4501-bbb1-7ce1fa996cde

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 15,395; copy number 2: 42,241; copy number 3: 2,159; copy number 4: 5; copy number 6: 2; copy number 7: 4; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:148,028,046–148,127,233, 4 genes: AC092958.4, LINC02032, AC092958.3, AC092958.2.
- chr3:148,166,344–148,167,298, 1 gene: HNRNPA1P20.
- chr4:186,191,567–186,289,681, 3 genes (within-gene range 0–1): CYP4V2, KLKB1, F11.
- chr12:78,052,181–78,091,737, 1 gene (within-gene range 0–2): AC073571.1.
- chr16:6,873,899–7,126,639, 3 genes: RNU6-457P, RNU6-328P, AC022206.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:52,494,688–52,500,752, 1 gene, copy number 7: AC139712.1.
- chr5:23,262,159–23,305,143, 3 genes, copy number 7: AC010460.2, Y_RNA, AC010460.3.
- chr5:34,245,273–34,373,850, 2 genes, copy number 6 (within-gene range 3–6): AC138409.3, AC138853.1.
- chr15:76,586,647–76,586,691, 1 gene, copy number 12: MIR3713.

Autosomal genes at a single copy (total copy number 1): 15,361. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
